Somatic mutation profile of tumor specimen TCGA-ZS-A9CF-01A (aliquot TCGA-ZS-A9CF-01A-11D-A382-10) from TCGA case TCGA-ZS-A9CF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 64.4 years (23,510 days).
Specimen TCGA-ZS-A9CF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1edbdbf7-2009-4686-a165-40d92fbc59f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZS-A9CF-10A (Blood Derived Normal), aliquot TCGA-ZS-A9CF-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47e86934-eedc-46c2-9a00-858b6b8aabab

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 23, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 2, Intron 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.5615G>T p.C1872F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1391686200, COSV99565852; called by muse, mutect2, varscan2
- AFP | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.446); catalogued as COSV99889782, COSV99890019; called by muse, mutect2, varscan2
- ATAD1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058219; called by muse, mutect2, varscan2
- CACNG8 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 29/33 reads (88%) | catalogued as COSV99555008; called by muse, mutect2, varscan2
- CNBD2 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs745724867, COSV100839104; called by muse, mutect2, varscan2
- COL4A1 | c.4733G>A p.W1578* | Nonsense Mutation (SNP) | VAF 84/153 reads (55%) | catalogued as COSV101011194; called by muse, mutect2, varscan2
- CSK | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV54972636, COSV99583865; called by muse, mutect2, varscan2
- DISP3 | c.3871G>C p.V1291L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV53821587, COSV99608732; called by muse, mutect2, varscan2
- DRP2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs369730985, COSV100871921; called by muse, mutect2, varscan2
- DRP2 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100871922, COSV104425958; called by muse, mutect2, varscan2
- ELF5 | c.79T>C p.C27R (on ENST00000312319 / NM_198381.2; = p.C17R on NM_001422.4) | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs1287219257, COSV99141209; called by muse, mutect2, varscan2
- EPG5 | c.2565C>G p.Y855* | Nonsense Mutation (SNP) | VAF 149/221 reads (67%) | catalogued as COSV99957313; called by muse, mutect2, varscan2
- EVPL | c.4759C>G p.Q1587E | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100044589; called by muse, mutect2, varscan2
- F5 | c.1239G>T p.M413I | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100889116; called by muse, mutect2, varscan2
- FAM47B | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 83/87 reads (95%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs781613588, COSV100264354; called by muse, mutect2, varscan2
- FBXO38 | c.2809A>T p.I937F (on ENST00000340253 / NM_205836.3; = p.I862F on NM_030793.5) | Missense Mutation (SNP) | VAF 94/101 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99693473; called by muse, mutect2, varscan2
- FNDC8 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99339061; called by muse, mutect2, varscan2
- FOXD4L3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100731009; called by muse, mutect2, varscan2
- GLI2 | c.2281G>A p.G761R (on ENST00000361492 / NM_001374353.1; = p.G778R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 278/630 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV58037899; called by muse, mutect2, varscan2
- GRIA1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 125/307 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53597752; called by muse, mutect2, varscan2
- HERC1 | c.7601T>A p.I2534K | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV101496590; called by muse, mutect2, varscan2
- INAVA | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.635); catalogued as rs1411235480, COSV100950007; called by muse, mutect2, varscan2
- IRAK1BP1 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 286/361 reads (79%) | catalogued as COSV100884877; called by muse, mutect2, varscan2
- ITPR1 | c.2585A>T p.K862M (on ENST00000354582; = p.K847M on NM_002222.7) | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100229107, COSV100233023; called by muse, mutect2
- KCNA4 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs970020205, COSV100068963; called by muse, mutect2, varscan2
- KIF19 | c.2090C>G p.A697G | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100739076; called by muse, mutect2, varscan2
- KRT6A | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 111/297 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs749357737, COSV58108441; called by muse, mutect2, varscan2
- LCT | c.2140A>T p.N714Y | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV99929561; called by muse, mutect2, varscan2
- LGALS9 | c.1002G>T p.R334S (on ENST00000395473 / NM_009587.3; = p.R302S on NM_002308.4) | Missense Mutation (SNP) | VAF 378/832 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV100119463; called by muse, mutect2, varscan2
- MAGEB1 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100974915; called by muse, mutect2
- MED12L | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 104/178 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99853267; called by muse, mutect2, varscan2
- MMUT | c.1045G>C p.A349P | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99222547; called by muse, mutect2, varscan2
- MUC16 | c.32086A>T p.R10696* | Nonsense Mutation (SNP) | VAF 56/131 reads (43%) | catalogued as COSV101201393; called by muse, mutect2, varscan2
- MYH1 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV56844884, COSV56850131; called by muse, mutect2, varscan2
- MYH2 | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs926577766, COSV99820217; called by muse, mutect2, varscan2
- MYOCD | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs750753749, COSV100590818; called by muse, mutect2, varscan2
- NBR1 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100357847; called by muse, mutect2, varscan2
- NCALD | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV55272708, COSV99637276, COSV99637399; called by muse, mutect2, varscan2
- NCAM2 | c.1205A>T p.K402M | Missense Mutation (SNP) | VAF 120/312 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99523173; called by muse, mutect2, varscan2
- NFATC2 | c.1070A>C p.Q357P | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV101044147; called by muse, mutect2, varscan2
- NRG2 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as COSV56832574, COSV99180337; called by muse, mutect2, varscan2
- NTRK2 | c.2189T>G p.F730C (on ENST00000323115 / NM_001369534.1; = p.F746C on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455507; called by muse, mutect2, varscan2
- OR1K1 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs781701473, COSV99474278; called by muse, mutect2, varscan2
- OR4F4 | c.296T>A p.F99Y | Missense Mutation (SNP) | VAF 53/393 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100055396; called by muse, mutect2, varscan2
- OR4M1 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100271230; called by muse, mutect2, varscan2
- OR5H14 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs917182258, COSV101454191; called by muse, mutect2, varscan2
- OR8H2 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100542342; called by muse, mutect2, varscan2
- PCLO | c.6760G>A p.D2254N | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); catalogued as rs1402428469, COSV61646063; called by muse, mutect2, varscan2
- PHYHIP | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 63/71 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100395137; called by muse, mutect2, varscan2
- PIWIL4 | c.257G>C p.C86S | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100133250; called by muse, mutect2, varscan2
- PRAME | c.1445T>G p.L482R | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101287092, COSV101287296; called by muse, mutect2, varscan2
- PRRC2A | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs1454783031, COSV100784582; called by muse, mutect2, varscan2
- PXDN | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs374347969; called by muse, mutect2, varscan2
- RNF19A | c.1237A>C p.N413H | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100347729; called by muse, mutect2, varscan2
- RORA | c.197-2A>T p.X66_splice (on ENST00000335670 / NM_134261.3; = p.X91_splice on NM_002943.3) | Splice Site (SNP) | VAF 80/176 reads (45%) | catalogued as COSV99832716; called by muse, mutect2, varscan2
- SCAP | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 107/215 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs997089172, COSV99650601; called by muse, mutect2, varscan2
- SERPINA7 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 71/81 reads (88%) | catalogued as COSV100568331; called by muse, mutect2, varscan2
- SLC27A1 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1485558386, COSV99393342; called by muse, mutect2, varscan2
- SMYD3 | c.230A>G p.K77R (on ENST00000490107 / NM_001375962.1; = p.K18R on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as COSV101194042; called by muse, mutect2, varscan2
- SPRY2 | c.600del p.C201Afs*12 | Frame Shift Del (DEL) | VAF 45/128 reads (35%) | catalogued as COSV101001657; called by mutect2, pindel, varscan2
- SYNJ1 | c.3218C>T p.S1073L | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs1301819492, COSV100449329; called by muse, mutect2, varscan2
- TNNI2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762215990, COSV53288930; called by muse, mutect2, varscan2
- TRERF1 | c.2667G>C p.K889N | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs752855299, COSV100550795; called by muse, mutect2, varscan2
- TRMT13 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs1453054588, COSV100924015; called by muse, mutect2, varscan2
- UBR3 | c.5277G>C p.Q1759H | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99774142; called by muse, mutect2, varscan2
- UGT2B7 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV100535207; called by muse, mutect2, varscan2
- VARS1 | c.786G>C p.E262D | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as COSV100989934; called by muse, mutect2, varscan2
- ZDHHC9 | c.434A>T p.K145M | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100852295; called by muse, mutect2, varscan2
- ZFPM2 | c.40C>A p.R14= | Splice Region (SNP) | VAF 156/319 reads (49%) | catalogued as COSV101342977, COSV101343243; called by muse, mutect2, varscan2
- AKR1C2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2
- ALB | c.482+5_482+8del p.X161_splice | Splice Site (DEL) | VAF 26/74 reads (35%) | called by pindel, varscan2
- CASP3 | c.674_676delinsCG p.Q225Pfs*100 | Frame Shift Del (DEL) | VAF 69/235 reads (29%) | called by pindel, varscan2*
- GLDC | c.618_619dup p.L207Hfs*25 | Frame Shift Ins (INS) | VAF 29/90 reads (32%) | called by mutect2, pindel, varscan2
- GUCY1A1 | c.251del p.P84Qfs*6 | Frame Shift Del (DEL) | VAF 45/120 reads (38%) | called by mutect2, pindel, varscan2
- JCHAIN | c.458del p.P153Qfs*13 | Frame Shift Del (DEL) | VAF 90/228 reads (39%) | called by mutect2, pindel, varscan2
- AGPS | c.6G>T p.A2= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99931345; called by muse, mutect2, varscan2
- ASXL1 | c.3508T>C p.L1170= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV100039370, COSV60117034; called by muse, mutect2, varscan2
- BARD1 | c.15G>T p.R5= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV99638755; called by muse, mutect2, varscan2
- BPIFB6 | c.273G>A p.V91= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100848519; called by muse, mutect2, varscan2
- CEP162 | c.390G>A p.E130= | Silent (SNP) | VAF 35/41 reads (85%) | catalogued as COSV57621994; called by muse, mutect2, varscan2
- CSF1R | c.2331G>A p.R777= | Silent (SNP) | VAF 49/60 reads (82%) | catalogued as COSV53828354; called by muse, mutect2, varscan2
- FPGS | c.36A>T p.L12= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV100948820; called by muse, mutect2
- GDF2 | c.207C>T p.S69= | Silent (SNP) | VAF 60/119 reads (50%) | catalogued as rs1229631161; called by muse, mutect2, varscan2
- GNA15 | c.678G>T p.V226= | Silent (SNP) | VAF 43/74 reads (58%) | catalogued as COSV99505230; called by muse, mutect2, varscan2
- KRTAP10-9 | c.690T>G p.S230= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100555343; called by muse, mutect2, varscan2
- MEGF8 | c.48C>T p.A16= | Silent (SNP) | VAF 121/253 reads (48%) | catalogued as rs777922711, COSV99236522; called by muse, mutect2, varscan2
- MYBPC1 | c.1315C>T p.L439= (on ENST00000550270 / NM_206820.2; = p.L464= on NM_002465.4) | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as COSV100638027; called by muse, mutect2, varscan2
- OSBPL6 | c.546T>C p.Y182= | Silent (SNP) | VAF 77/191 reads (40%) | catalogued as COSV99507516; called by muse, mutect2, varscan2
- PAX2 | c.1038C>A p.P346= (on ENST00000428433 / NM_003987.5; = p.P323= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1436701401, COSV100695191; called by muse, mutect2, varscan2
- PROM2 | c.459C>A p.A153= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV100469024; called by muse, mutect2, varscan2
- RABGAP1 | c.69A>G p.E23= | Silent (SNP) | VAF 57/117 reads (49%) | catalogued as rs1302726606, COSV100438589; called by muse, mutect2, varscan2
- RYR2 | c.6552C>G p.S2184= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV100772607; called by muse, mutect2, varscan2
- SCN11A | c.735C>A p.A245= | Silent (SNP) | VAF 74/195 reads (38%) | catalogued as COSV56569806; called by muse, mutect2, varscan2
- SLC6A8 | c.1431G>C p.S477= | Silent (SNP) | VAF 73/76 reads (96%) | catalogued as COSV99465953; called by muse, mutect2, varscan2
- TSNAX | c.672T>C p.V224= | Silent (SNP) | VAF 99/229 reads (43%) | catalogued as COSV100791109; called by muse, mutect2, varscan2
- TTN | c.44028T>A p.T14676= (on ENST00000591111; = p.T7252= on NM_003319.4) | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV100614476; called by muse, mutect2, varscan2
- ZBTB37 | c.729A>G p.V243= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as COSV100774594; called by muse, mutect2, varscan2
- ZIM2 | c.1101C>A p.L367= | Silent (SNP) | VAF 55/66 reads (83%) | catalogued as COSV55634935, COSV55644582, COSV99689073; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+17A>C | Intron (SNP) | VAF 27/53 reads (51%) | catalogued as COSV99180710; called by muse, mutect2, varscan2
- UBTFL2 | n.564G>A | RNA (SNP) | VAF 64/185 reads (35%) | called by muse, mutect2, varscan2
